Somatic mutation profile of tumor specimen MMRF_1686_1_BM_CD138pos (aliquot MMRF_1686_1_BM_CD138pos_T1_KBS5U_L06418) from MMRF case MMRF_1686, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 38.0 years (13,869 days).
Specimen MMRF_1686_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb6d9f3c-00df-4fbd-b978-cd32c6d1157a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1686_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1686_1_PB_Whole_C3_KBS5U_L06465; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38487113-b34d-4c0c-9176-2cc2ae937774

The open-access MAF lists 49 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, 3'UTR 15, Intron 9, Silent 5, 5'UTR 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.2996T>C p.M999T | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV67796663; called by muse, mutect2, varscan2
- IGHJ4 | c.3C>G p.Y1* | Nonsense Mutation (SNP) | VAF 35/72 reads (49%) | catalogued as rs368028316; called by muse, varscan2
- IGKV3-20 | c.284C>G p.T95S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs779765601; called by muse, varscan2
- KLHL4 | c.1217A>G p.Y406C | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64141428; called by muse, mutect2, varscan2
- PAK1 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.088); catalogued as COSV53694861; called by muse, mutect2, varscan2
- ROR1 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756584494, COSV64291231; called by muse, mutect2, varscan2
- SCARA5 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1434449808, COSV57276567; called by muse, mutect2, varscan2
- UACA | c.2206_2210del p.L736Nfs*2 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | catalogued as rs746217937; called by mutect2, pindel, varscan2
- ANKIB1 | c.1758G>C p.E586D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ARL13B | c.642A>T p.Q214H (on ENST00000394222 / NM_001174150.2; = p.Q107H on NM_144996.4) | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ARL6IP5 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CDKN1B | c.183T>A p.N61K | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2
- CDKN1B | c.185T>G p.F62C | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DKK2 | c.501A>T p.R167S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DMRTA1 | c.1183C>G p.L395V | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- FMO5 | c.202A>G p.M68V | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- SAP30BP | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ANK2 | c.729C>T p.Y243= | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as rs773812842, COSV52146516; called by muse, mutect2, varscan2
- BRD2 | c.4C>T p.L2= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as rs750308944; called by muse, mutect2, varscan2
- CD83 | c.42C>T p.Y14= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as rs1194151926; called by muse, mutect2, varscan2
- NKX2-5 | c.405G>A p.A135= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV61298505; called by muse, mutect2, varscan2
- PRR23B | c.744G>A p.S248= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1175231356, COSV100271998; called by muse, mutect2, varscan2
- ACOT13 | c.*3402T>G | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- AGPS | c.*561A>T | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs1256758261; called by muse, varscan2
- AIFM3 | c.-140-62G>A | Intron (SNP) | VAF 16/32 reads (50%) | catalogued as rs1024028384, COSV59000107; called by muse, mutect2, varscan2
- ATP11C | c.*1858A>C | 3'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- BTG2 | c.*1013G>T | 3'UTR (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- C2orf49 | c.*3555T>G | 3'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- C7orf61 | c.-67A>C | 5'UTR (SNP) | VAF 10/29 reads (34%) | catalogued as rs879202625; called by muse, mutect2
- DIP2C | c.*855A>T | 3'UTR (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- FGR | c.-13-82G>A | Intron (SNP) | VAF 18/69 reads (26%) | catalogued as rs956073263; called by muse, mutect2, varscan2
- FUT8 | c.*652A>G | 3'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- GSDMC | c.916+31G>A | Intron (SNP) | VAF 32/93 reads (34%) | catalogued as rs1301734494; called by muse, mutect2, varscan2
- IGHV1-69D | c.-13A>G | 5'UTR (SNP) | VAF 7/25 reads (28%) | called by mutect2, varscan2
- IL1RL1 | c.970+1318C>A | Intron (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- KRT38 | c.*212G>T | 3'UTR (SNP) | VAF 22/74 reads (30%) | catalogued as rs1275796354; called by muse, varscan2
- LCLAT1 | c.743-32907G>C | Intron (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- LGI1 | c.216-91C>T | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- MLXIPL | c.1822+72G>A | Intron (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- NUP107 | c.1999-52T>A | Intron (SNP) | VAF 5/46 reads (11%) | catalogued as rs1159696280, COSV57494996; called by muse, varscan2
- OSMR | c.*1319C>T | 3'UTR (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- SCN9A | c.*292T>A | 3'UTR (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- SGSH | c.949+124G>A | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- SLC25A53 | c.*3919A>G | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- SLIT1 | c.*540C>T | 3'UTR (SNP) | VAF 17/104 reads (16%) | catalogued as rs1031652251; called by muse, mutect2, varscan2
- SLITRK2 | c.-3503T>G | 5'UTR (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- TRIM71 | c.*137A>T | 3'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as rs1239818666, COSV67470745; called by muse, mutect2
- ZMAT1 | c.*387G>A | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- ZNF791 | c.*738_*753del | 3'UTR (DEL) | VAF 24/116 reads (21%) | called by mutect2, pindel, varscan2
